Gene-level copy-number profile of tumor specimen C3N-00148-01 from CPTAC case C3N-00148, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 52.9 years (19,314 days).
Specimen C3N-00148-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e37f5d3c-4eb1-44fe-98ea-bd42865739d8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00148-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/d6b818ab-e4fe-4649-b553-a8b2f7814c4e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 521; copy number 2: 8,863; copy number 3: 2,893; copy number 4: 40,541; copy number 5: 198; copy number 6: 5,848; copy number 7: 10; copy number 8: 5; copy number 9: 10; copy number 11: 1; copy number 14: 6; copy number 17: 8.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:46,712,115–46,812,574, 8 genes (within-gene range 0–2): AC109583.1, PRSS50, PRSS46P, PRSS45P, AC109583.4, PRSS43P, AC109583.2, PRSS44P.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 25 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:89,295–522,928, 16 genes, copy number 9–14: AL627309.1, AL627309.3, CICP27, AL627309.6, AL627309.7, AL627309.2, RNU6-1100P, AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6.
- chr1:587,629–594,768, 1 gene, copy number 9: AC114498.1.
- chr1:144,085,628–144,373,659, 8 genes, copy number 17: IGKV1OR1-1, AC244015.1, AC244015.2, LINC02802, RNA5SP529, DRD5P2, AC245595.1, PPIAL4E.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
